Gene-level copy-number profile of tumor specimen TCGA-D5-6535-01A from TCGA case TCGA-D5-6535, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Colon, NOS; AJCC pathologic stage: Stage IIIB; Age at diagnosis: 80.2 years (29,278 days).
Specimen TCGA-D5-6535-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-COAD.ca79ce1b-b8da-4e44-b227-1e24981b13a4.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-D5-6535-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 812 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/b300b164-dff7-407f-92a3-17cd6312e3a4

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 7; copy number 1: 1,549; copy number 2: 16,458; copy number 3: 21,021; copy number 4: 17,418; copy number 5: 2,281; copy number 6: 1,073; copy number 9: 4.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-D5-6535-01A-11D-1717-01): tumor purity 0.61, ploidy 3.06, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): 7 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr16:6,573,767–6,874,005, 5 genes: AC007223.1, AC007012.2, AC007012.1, RNU7-99P, RNU6-457P.
- chr20:14,757,563–14,929,528, 2 genes (within-gene range 0–1): RPS10P2, MACROD2-AS1.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 4 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:50,603,229–50,846,519, 4 genes, copy number 9 (within-gene range 3–9): AC112187.2, AC112187.1, AC112187.3, PARP8.

Autosomal genes at a single copy (total copy number 1): 1,549. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
